HCMI case HCM-BROD-1104-C85 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Malignant Lymphomas, NOS or Diffuse; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/42f8ece8-70dc-48b8-a9ec-28dc218a735a

Demographics
Sex at birth: male; Race: white; Year of birth: 1949.

Diagnoses (1)
1. Malignant lymphoma, non-Hodgkin, NOS: ICD-O-3 morphology code: 9591/3; ICD-10 code: C85.9; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Classification of tumor: primary; Age at diagnosis: 64.7 years (23,617 days); Prior malignancy: no; Prior treatment: No.
   Pathology details: Bone marrow malignant cells: Yes; Lymphatic invasion present: Yes.
   Recorded as not given: neoadjuvant treatment (type not reported); Surgery, NOS, for initial diagnosis.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 64.

Molecular and laboratory tests
- IGH–BCL2 rearrangement (Cytogenetics, NOS): Positive.
- MYC rearrangement (FISH): Positive.
- Leukocytes 408 ×10³/µL.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Methicillin-Resistant Staphylococcus aureus (MRSA) / COPD; Risk factors: COPD.
- Timepoint category: Initial Diagnosis; Weight: 113 kg; Height: 177 cm; BMI: 36.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol drinks per day: 1; Alcohol days per week: 2.

Family history
- Relative with cancer history: no.

Biospecimens (1 sample)
- Sample HCM-BROD-1104-C85-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
